Gene-level copy-number profile of tumor specimen TCGA-IQ-7632-01A from TCGA case TCGA-IQ-7632, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 68.4 years (24,986 days).
Specimen TCGA-IQ-7632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.75c29b49-e222-49f2-b827-a684982adbdc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IQ-7632-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b41be792-937e-4f1c-9fdb-3eb6d26d1c5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 1,953; copy number 2: 50,208; copy number 3: 6,519; copy number 4: 790; copy number 15: 136; copy number 22: 91; copy number 37: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IQ-7632-01A-11D-2077-01): tumor purity 0.24, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,383,217–27,230,174, 115 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 235 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:46,781,373–57,837,046, 235 genes, copy number 15–37 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,953. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
